Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A6AO, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A6AO-01A (Primary Tumor).

[page 1 of 2]
Sex: Male
D.O.B.:
MRN #:
Ref Phy:...

SPECIMEN INFO

Collected:
Received:
Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Right lateral margin:
Benign, no pathologic diagnosis.
- B. Apical margin:
Benign, no pathologic diagnosis.
- C. Left apical margin:
Benign, no pathologic diagnosis.
- D. Radical prostatectomy:
Carcinoma.

Tumor Characteristics:

- Histologic type: Adenocarcinoma, usual type.
- Prostate size: 38 grams, 5.0 x 4.5 x 4.5 cm.
- Tumor quantitation: approximately 5% of gland volume.
- Gleason grade:
- Primary pattern: 4/5.
- Secondary pattern: 3/5.
- Total Gleason score: 7/10.
- Extraprostatic extension: Not identified.
- Seminal vesicle involvement: Not identified.
- Lymphovascular space invasion: Not identified.
- High grade PIN: Present.
- Perineural invasion: Not identified.
- Extent of tumor: Bilateral.
- Treatment effect: Not identified.

Surgical Margin Status:

1. Margins uninvolved.

Lymph Node Status:

1. Total number of lymph nodes received: None.

Other:

- Other significant findings: None.
- pTNM stage: pT2c,NX.

CLF ICD-O-3
Adenocarcinoma, acinar 8140/3
path
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
QJ 5/16/13

Electronic Signature:

CLINICAL HISTORY

CLINICAL HISTORY:

Preoperative Diagnosis: None given
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- Right lateral margin
- Apical margin
- Left apical margin
- Prostate

GROSS DESCRIPTION:

[page 2 of 2]
- A. The first container A is received in formalin labeled _____ right lateral margin. The specimen consists of a piece of brown tan soft tissue measuring 0.2 x 0.1 x 0.1 cm. The specimen is entirely submitted in a single cassette labeled _____
- B. The second container B is received in formalin labeled _____ ical margin. The specimen consists of a piece of brown tan soft tissue measuring 0.3 x 0.2 x 0.1 cm. The specimen is entirely submitted in a single cassette labeled _____
- C. The third container C is received in formalin labeled _____ left apical margin. The specimen consists of a piece of yellow tan soft tissue measuring 0.2 x 0.1 x 0.1 cm. The specimen is entirely submitted in a single cassette labeled _____
- D. The specimen consists of a prostate gland with attached bilateral seminal vesicles and vas deferens. The prostate measures 5.0 x 4.5 x 4.5 cm and weighs 38 grams. The right seminal vesicle measures 3.5 cm in length and 1.0 cm in diameter and the left seminal vesicle measuring 2.0 cm in length and 1.5 cm in diameter. Both are grossly unremarkable. The right vas deferens measures 6.5 cm in length and 0.2 cm in diameter and the right vas deferens measures 6.0 cm in length and 0.2 cm in diameter. Both are grossly unremarkable. The surface of the prostate is gray tan to brown tan with adhesions. The right half has been inked red and the left half has been inked blue. The prostate is serially sectioned from apex to base. On sectioning the cut surface is yellow to gray tan fibrous with yellow tan gritty areas that involve both the right and left posterior lobes, involving primarily apex and base areas. No other lesions are identified. Received with the specimen are two cassettes, one yellow, one green, labeled _____ as follows: right seminal vesicle and vas--1; left seminal vesicle and vas--2; perpendicular sections taken from the margins from apex--3; base--4; prostate submitted from apex to base as follows: level 1 left anterior--5; left posterior--6; right posterior--7; right anterior--8; level 2 left anterior--9; left posterior--10; right posterior--11; right anterior--12; level 3 left anterior--13; left posterior--14; right posterior--15; right anterior--16.

QVQA Discrepancy		✓
Discrepancy in Primary Tumor		✓

Source: NCI Genomic Data Commons file df8f861b-c527-4d8d-a031-84b4ecec0b4b (TCGA-HC-A6AO.37F41695-9D8D-4CA1-9728-6A04AAD76274.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).